Somatic mutation profile of tumor specimen C3L-07988-03 (aliquot CPT0481520006) from CPTAC case C3L-07988, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 72.1 years (26,317 days).
Specimen C3L-07988-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6c6eb97-123e-47b5-b4d4-fa1af43a25ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07988-31 (Blood Derived Normal), aliquot CPT0481650003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bdf1f3b-73da-4d08-ae4d-37bb8b3618ae

The open-access MAF lists 1,143 somatic variants for this specimen: 853 protein-altering or splice-affecting, 244 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 630, Silent 244, Frame Shift Del 160, Frame Shift Ins 30, Intron 20, Nonsense Mutation 18, 3'UTR 13, Splice Region 6, Splice Site 6, 5'Flank 4, 5'UTR 3, 3'Flank 3.

Variants (750 of 1,143; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 60/481 reads (12%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KCNMA1 | c.2026del p.Y676Tfs*15 | Frame Shift Del (DEL) | VAF 49/260 reads (19%) | catalogued as rs762705295; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 48/256 reads (19%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- LHX4 | c.293dup p.T99Nfs*54 | Frame Shift Ins (INS) | VAF 80/331 reads (24%) | catalogued as rs587776662; ClinVar: pathogenic; called by mutect2, varscan2
- MKRN3 | c.482del p.P161Rfs*10 | Frame Shift Del (DEL) | VAF 93/502 reads (19%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NF1 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 12/229 reads (5%) | hotspot (GDC flag); catalogued as rs878853865, CM000780, COSV62194747; ClinVar: pathogenic; called by muse, mutect2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 41/411 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2
- RSPH4A | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 89/450 reads (20%) | catalogued as rs1034327724, COSV57633705; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCB1 | c.351dup p.T118Hfs*6 (on ENST00000263121; = p.T118Hfs*52 on NM_003073.5) | Frame Shift Ins (INS) | VAF 70/371 reads (19%) | catalogued as rs1555876140; ClinVar: pathogenic; called by pindel, varscan2
- A2M | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs774209449; called by muse, mutect2, varscan2
- ABCA13 | c.10508del p.N3503Tfs*28 | Frame Shift Del (DEL) | VAF 48/355 reads (14%) | catalogued as rs759644486; called by mutect2, pindel, varscan2
- ABCG1 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 55/294 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0.182); catalogued as rs1184783690; called by muse, mutect2, varscan2
- ABCG1 | c.1561G>A p.V521M | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs374879637; called by muse, mutect2, varscan2
- ADAM10 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 23/301 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as rs1247356544; called by muse, mutect2
- ADCY3 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 85/415 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV53172390; called by muse, mutect2, varscan2
- ADGRV1 | c.3439T>G p.F1147V | Missense Mutation (SNP) | VAF 12/375 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs1162893004; called by muse, mutect2
- AKAP1 | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758710258, COSV100533166; called by muse, mutect2, varscan2
- AKT1 | c.954del p.E319Rfs*24 | Frame Shift Del (DEL) | VAF 48/289 reads (17%) | catalogued as COSV62572709; called by mutect2, pindel, varscan2
- AL355102.2 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 82/424 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1351894248, COSV99388042; called by muse, mutect2, varscan2
- ALDH3A2 | c.527A>C p.Q176P | Missense Mutation (SNP) | VAF 22/427 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV51565715; called by muse, mutect2
- AMPH | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 26/340 reads (8%) | catalogued as rs868741417, COSV57759420; called by muse, mutect2
- ANKLE1 | c.879dup p.W294Lfs*24 (on ENST00000394458; = p.W240Lfs*24 on NM_152363.6) | Frame Shift Ins (INS) | VAF 47/436 reads (11%) | catalogued as rs750088587; called by mutect2, pindel, varscan2
- ANKRD33B | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 75/375 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1358562200; called by muse, mutect2, varscan2
- ANO8 | c.1087del p.L363Cfs*24 | Frame Shift Del (DEL) | VAF 117/553 reads (21%) | catalogued as COSV50178856; called by mutect2, pindel, varscan2
- APBA2 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 59/707 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1291789171, COSV68794329; called by muse, mutect2
- ARAP3 | c.1810C>T p.R604W | Missense Mutation (SNP) | VAF 99/454 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53349126; called by muse, mutect2, varscan2
- ARFGAP3 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199746732; called by muse, mutect2, varscan2
- ARHGAP23 | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 89/420 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1176986034; called by muse, mutect2, varscan2
- ARHGAP4 | c.2219C>T p.A740V | Missense Mutation (SNP) | VAF 59/368 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs782660805; called by muse, mutect2, varscan2
- ARHGAP45 | c.842del p.G281Afs*16 | Frame Shift Del (DEL) | VAF 82/434 reads (19%) | catalogued as COSV57429840; called by mutect2, pindel, varscan2
- ARHGEF40 | c.248G>A p.C83Y | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs774840976; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 82/447 reads (18%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID4B | c.3666G>A p.S1222= | Splice Region (SNP) | VAF 39/198 reads (20%) | catalogued as rs745757772, COSV99936273; called by muse, mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 75/422 reads (18%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATP10A | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as rs138618267; called by muse, mutect2, varscan2
- ATP13A5 | c.2659T>C p.C887R | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1352226559; called by muse, mutect2, varscan2
- ATP8A2 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs772349695; called by muse, mutect2, varscan2
- AXDND1 | c.1142T>C p.L381S | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs1435440152; called by muse, mutect2
- AZU1 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 118/566 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs762731829; called by muse, mutect2, varscan2
- B3GALT5 | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 103/491 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.149); catalogued as rs369365169; called by muse, mutect2, varscan2
- BAP1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 81/423 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220529268, COSV56235828; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCR | c.2351T>C p.L784P | Missense Mutation (SNP) | VAF 78/356 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100006751; called by muse, mutect2, varscan2
- BIN3 | c.338del p.K113Sfs*13 | Frame Shift Del (DEL) | VAF 47/389 reads (12%) | catalogued as rs776003776; called by mutect2, varscan2
- BOD1L1 | c.8330A>G p.Y2777C | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1393252843; called by muse, mutect2, varscan2
- BRD1 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs764429512, COSV99350226; called by muse, mutect2, varscan2
- BRSK1 | c.1675A>C p.S559R | Missense Mutation (SNP) | VAF 51/498 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV58665671; called by muse, mutect2
- BUD23 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs370514850; called by muse, mutect2, varscan2
- C2orf73 | c.309del p.F103Lfs*17 | Frame Shift Del (DEL) | VAF 42/340 reads (12%) | catalogued as rs747496393; called by pindel, varscan2
- C3orf80 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 64/628 reads (10%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.106); catalogued as rs1200153919, COSV100426008; called by muse, mutect2, varscan2
- C5orf22 | c.772del p.S258Qfs*31 | Frame Shift Del (DEL) | VAF 40/246 reads (16%) | catalogued as rs751259551; called by mutect2, varscan2
- CAND1 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 41/381 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.365); catalogued as rs763189890; called by muse, mutect2, varscan2
- CAPG | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 44/432 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs185763147, COSV55708808; called by muse, mutect2, varscan2
- CCDC166 | c.250_251dup p.Q85Pfs*19 | Frame Shift Ins (INS) | VAF 114/541 reads (21%) | catalogued as rs781837594; called by mutect2, varscan2
- CCDC168 | c.4708G>A p.D1570N | Missense Mutation (SNP) | VAF 99/443 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs561975322; called by muse, mutect2, varscan2
- CCDC78 | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 18/458 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99557276; called by muse, mutect2
- CCDC88C | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773103876; called by muse, mutect2, varscan2
- CCR3 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 78/406 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs201512005; called by muse, mutect2, varscan2
- CD93 | c.943dup p.A315Gfs*34 | Frame Shift Ins (INS) | VAF 40/372 reads (11%) | catalogued as rs747115137; called by mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 52/251 reads (21%) | catalogued as rs762194001; called by mutect2, varscan2
- CDK20 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 56/343 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs373621335; called by muse, mutect2, varscan2
- CEP128 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs200135744, COSV55373956; called by muse, varscan2
- CFAP44 | c.3423del p.E1142Nfs*35 | Frame Shift Del (DEL) | VAF 23/202 reads (11%) | catalogued as rs947129972; called by pindel, varscan2
- CFHR5 | c.147A>C p.E49D | Missense Mutation (SNP) | VAF 34/305 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as COSV56823507, COSV56823864; called by muse, mutect2, varscan2
- CIC | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 69/386 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1006476018; called by muse, mutect2, varscan2
- CLECL1 | c.159A>C p.E53D | Missense Mutation (SNP) | VAF 58/356 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.402); catalogued as rs754069990, COSV100590053; called by muse, varscan2
- CNGB1 | c.3559C>T p.R1187W | Missense Mutation (SNP) | VAF 110/550 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs564918974; called by muse, mutect2, varscan2
- COG6 | c.866del p.G289Afs*17 | Frame Shift Del (DEL) | VAF 60/368 reads (16%) | catalogued as rs1566179913; called by mutect2, pindel, varscan2
- COG7 | c.1756G>A p.V586M | Missense Mutation (SNP) | VAF 66/393 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs368832315; called by muse, mutect2, varscan2
- COG8 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 89/423 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs749893629, COSV54742902, COSV99650661; called by muse, mutect2, varscan2
- COLGALT1 | c.1376G>A p.G459D | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs777777218; called by muse, mutect2, varscan2
- COX10 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 54/450 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55408078; called by muse, mutect2, varscan2
- CPAMD8 | c.3153del p.H1052Ifs*127 (on ENST00000651564; = p.H1005Ifs*127 on NM_015692.5) | Frame Shift Del (DEL) | VAF 109/482 reads (23%) | catalogued as rs750161916, COSV71597321; called by mutect2, varscan2
- CPE | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 90/427 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1235670045, COSV68579489; called by muse, mutect2, varscan2
- CRACR2A | c.1567del p.R523Efs*40 | Frame Shift Del (DEL) | VAF 39/389 reads (10%) | catalogued as rs760934861; called by mutect2, pindel, varscan2
- CSNK1A1L | c.166del p.Q56Sfs*33 | Frame Shift Del (DEL) | VAF 73/442 reads (17%) | catalogued as COSV104429112; called by mutect2, pindel, varscan2
- CTNND1 | c.2091G>A p.T697= (on ENST00000399050 / NM_001085458.2; = p.T691= on NM_001331.3) | Splice Region (SNP) | VAF 18/320 reads (6%) | catalogued as COSV62385655; called by muse, mutect2
- CTSK | c.158del p.N53Tfs*2 | Frame Shift Del (DEL) | VAF 46/287 reads (16%) | catalogued as rs764168526; called by mutect2, pindel, varscan2
- CYP2J2 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 22/480 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1334569219; called by muse, mutect2
- DDA1 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 63/344 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs758181973; called by muse, mutect2, varscan2
- DDX20 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs187088183, COSV63831722; called by muse, mutect2, varscan2
- DDX39A | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1278206404; called by muse, mutect2, varscan2
- DDX43 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 110/480 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.057); catalogued as COSV100946233; called by muse, mutect2, varscan2
- DEAF1 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 73/319 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs141368610, COSV100102098; called by muse, mutect2, varscan2
- DGLUCY | c.1679A>G p.Q560R | Missense Mutation (SNP) | VAF 13/326 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV99824493; called by muse, mutect2
- DHDDS | c.681C>A p.F227L | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99360313; called by muse, mutect2
- DHX36 | c.2739del p.F913Lfs*18 | Frame Shift Del (DEL) | VAF 73/591 reads (12%) | catalogued as rs1291917756; called by mutect2, pindel, varscan2
- DIO2 | c.56del p.F19Sfs*23 | Frame Shift Del (DEL) | VAF 73/392 reads (19%) | catalogued as rs148778534; called by mutect2, pindel, varscan2
- DIP2C | c.3172C>T p.R1058C | Missense Mutation (SNP) | VAF 63/403 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765260096; called by muse, mutect2, varscan2
- DMD | c.4088A>G p.K1363R | Missense Mutation (SNP) | VAF 21/340 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.283); catalogued as COSV63732568, COSV63756777; called by muse, mutect2
- DMRTA1 | c.711A>C p.E237D | Missense Mutation (SNP) | VAF 42/281 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs771724739; called by muse, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 32/142 reads (23%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAJC30 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 53/526 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.018); catalogued as rs542580363; called by muse, mutect2
- DOCK10 | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 65/343 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.724); catalogued as rs775940262; called by muse, mutect2, varscan2
- DOP1A | c.7060C>T p.R2354* | Nonsense Mutation (SNP) | VAF 44/247 reads (18%) | catalogued as COSV52718460; called by muse, mutect2, varscan2
- DRC7 | c.2120A>C p.E707A | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs1199128551; called by muse, mutect2, varscan2
- DUSP9 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 18/516 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs1557035754; called by muse, mutect2
- DVL1 | c.1300C>T p.R434C (on ENST00000378888 / NM_001330311.2; = p.R409C on NM_004421.3) | Missense Mutation (SNP) | VAF 78/369 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1171248166; called by muse, mutect2, varscan2
- EBF2 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.15); catalogued as rs540831300; called by muse, mutect2, varscan2
- ECHDC2 | c.607G>A p.V203I (on ENST00000371522 / NM_001198961.2; = p.V172I on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/439 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs759233702; called by muse, mutect2, varscan2
- EIF5B | c.2069G>A p.R690K | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.042); catalogued as COSV56815629; called by muse, mutect2, varscan2
- ELAPOR2 | c.1471T>G p.L491V (on ENST00000450689 / NM_001142749.3; = p.L324V on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/295 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99789656; called by muse, mutect2
- ELMO2 | c.2115del p.I706Sfs*115 | Frame Shift Del (DEL) | VAF 66/329 reads (20%) | catalogued as rs1328663885; called by mutect2, pindel, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 67/274 reads (24%) | catalogued as rs753821453; called by mutect2, varscan2
- EVX2 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 119/563 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV99079562; called by muse, mutect2, varscan2
- FAM186A | c.1789A>G p.T597A | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV59247548; called by muse, mutect2
- FAM43B | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 120/517 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781482241; called by muse, mutect2, varscan2
- FASN | c.3392G>A p.R1131H | Missense Mutation (SNP) | VAF 47/338 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs147660865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT3 | c.9701dup p.V3235Cfs*3 | Frame Shift Ins (INS) | VAF 49/393 reads (12%) | catalogued as rs1399232408; called by mutect2, pindel
- FDFT1 | c.360G>T p.Q120H | Missense Mutation (SNP) | VAF 53/346 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs557080830; called by muse, mutect2, varscan2
- FER1L6 | c.3064G>A p.G1022R | Missense Mutation (SNP) | VAF 45/545 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs767427795, COSV67550153, COSV67551492; called by muse, mutect2
- FERMT3 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 73/352 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1438834162; called by muse, mutect2, varscan2
- FKRP | c.948del p.C317Afs*111 | Frame Shift Del (DEL) | VAF 89/425 reads (21%) | catalogued as rs748798133, CM0910304; called by mutect2, pindel, varscan2
- FMNL3 | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 79/387 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs369130733; called by muse, mutect2, varscan2
- GAL3ST3 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 81/404 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1210106692, COSV61749215; called by muse, mutect2, varscan2
- GALNT13 | c.1110A>C p.E370D | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV67214528; called by muse, mutect2, varscan2
- GET4 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 94/451 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); catalogued as rs752114502, COSV56214846; called by muse, mutect2, varscan2
- GFRAL | c.117A>C p.K39N | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.466); catalogued as COSV61231576; called by muse, mutect2, varscan2
- GGT2 | c.1311del p.S438Hfs*18 | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | catalogued as rs765742635; called by mutect2, varscan2
- GIGYF2 | c.3647A>C p.Q1216P | Missense Mutation (SNP) | VAF 30/515 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs201154978; called by muse, mutect2
- GIPC3 | c.685del p.A229Lfs*89 (on ENST00000644946; = p.A229Lfs*55 on NM_133261.3) | Frame Shift Del (DEL) | VAF 88/441 reads (20%) | catalogued as rs748150647, COSV99056389; called by mutect2, pindel, varscan2
- GLUD2 | c.1051T>G p.F351V | Missense Mutation (SNP) | VAF 112/514 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV100046867; called by muse, mutect2, varscan2
- GNS | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs575544204, COSV50696685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GOLGB1 | c.9679C>T p.R3227C | Missense Mutation (SNP) | VAF 46/420 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs543383996; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 83/313 reads (27%) | catalogued as rs370114090; called by mutect2, varscan2
- GPR150 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 46/376 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs1323508337; called by muse, mutect2, varscan2
- GPR158 | c.1439G>T p.R480L | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100893626; called by mutect2, varscan2
- GPR32 | c.977A>C p.K326T | Missense Mutation (SNP) | VAF 31/428 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV54514053; called by muse, mutect2
- GREB1 | c.3725T>C p.L1242P | Missense Mutation (SNP) | VAF 106/555 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs765274727; called by muse, mutect2, varscan2
- GRID2 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 77/356 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs754110902, COSV56172424; called by muse, mutect2, varscan2
- GRM1 | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 74/339 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99269381; called by muse, mutect2, varscan2
- GRM5 | c.3059C>T p.S1020L (on ENST00000305447 / NM_001143831.2; = p.S988L on NM_000842.4) | Missense Mutation (SNP) | VAF 19/490 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs1309769740; called by muse, mutect2
- H1-4 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 79/421 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56800181; called by muse, mutect2, varscan2
- H4C1 | c.44del p.G15Vfs*30 | Frame Shift Del (DEL) | VAF 53/287 reads (18%) | catalogued as rs776045633; called by mutect2, pindel, varscan2
- HCN2 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 86/410 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.29); catalogued as rs142072194; called by muse, varscan2
- HECTD3 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 86/417 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs201302909, COSV55800917; called by muse, mutect2, varscan2
- HELZ2 | c.5890G>A p.V1964I (on ENST00000467148 / NM_001037335.2; = p.V1395I on NM_033405.3) | Missense Mutation (SNP) | VAF 78/463 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs376824048; called by muse, mutect2, varscan2
- HES5 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 73/351 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762103606, COSV65830412; called by muse, mutect2, varscan2
- HFM1 | c.4200dup p.I1401Yfs*2 | Frame Shift Ins (INS) | VAF 24/164 reads (15%) | catalogued as rs766204131; called by mutect2, varscan2
- HIPK4 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 50/416 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV52527237; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 47/198 reads (24%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPUL1 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 60/388 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as rs1362442748; called by muse, mutect2, varscan2
- HPSE | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 36/464 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as COSV60986513; called by muse, mutect2
- HS3ST3A1 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 109/507 reads (21%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs1222288886; called by muse, mutect2, varscan2
- IFT140 | c.4298G>A p.R1433H | Missense Mutation (SNP) | VAF 124/519 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs138420849, COSV99248205; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGHMBP2 | c.1681A>G p.I561V | Missense Mutation (SNP) | VAF 80/342 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.402); catalogued as rs1019957486; called by muse, varscan2
- INSC | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777786881, COSV65413674; called by muse, mutect2, varscan2
- IQCM | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 96/453 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.882); catalogued as rs557393534, COSV101546648; called by muse, mutect2, varscan2
- IRS4 | c.3677del p.P1226Rfs*14 | Frame Shift Del (DEL) | VAF 87/507 reads (17%) | catalogued as COSV100929417; called by mutect2, pindel, varscan2
- ITGA9 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 89/458 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1474405958, COSV53252406; called by muse, mutect2, varscan2
- ITIH2 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 64/315 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs200935424, COSV64431976; called by muse, varscan2
- ITIH3 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 53/272 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs779431612; called by muse, mutect2, varscan2
- KBTBD4 | c.1413C>A p.S471R | Missense Mutation (SNP) | VAF 24/550 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as COSV100442803; called by muse, mutect2
- KCNG1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 52/477 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.1); catalogued as COSV65368649, COSV65370663; called by muse, mutect2, varscan2
- KCNG2 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 92/471 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs746775334; called by muse, mutect2, varscan2
- KCNQ5 | c.1258A>C p.S420R | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV59662086, COSV59665050; called by muse, mutect2, varscan2
- KCNT1 | c.2075C>T p.A692V (on ENST00000488444; = p.A711V on NM_020822.3) | Missense Mutation (SNP) | VAF 72/455 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs1312096992, COSV53696431; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 42/209 reads (20%) | catalogued as COSV54711577; called by mutect2, varscan2
- KLHDC7B | c.113G>T p.R38I (on ENST00000395676; = p.R679I on NM_138433.5) | Missense Mutation (SNP) | VAF 81/440 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV67464919; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 52/368 reads (14%) | catalogued as rs749194179; called by mutect2, varscan2
- KMT2B | c.1463G>T p.G488V | Missense Mutation (SNP) | VAF 48/620 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1389952141; called by muse, mutect2
- KRR1 | c.1142del p.K381Sfs*8 | Frame Shift Del (DEL) | VAF 26/145 reads (18%) | catalogued as rs761148574; called by mutect2, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 76/320 reads (24%) | catalogued as rs750491454; called by mutect2, varscan2
- LAMP1 | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 54/520 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as rs747575303; called by muse, mutect2, varscan2
- LANCL2 | c.900del p.K300Nfs*11 | Frame Shift Del (DEL) | VAF 96/481 reads (20%) | catalogued as rs1562867207; called by mutect2, pindel, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 54/308 reads (18%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LILRA1 | c.1099del p.L367Sfs*18 | Frame Shift Del (DEL) | VAF 118/510 reads (23%) | catalogued as rs766823529, COSV99252192; called by mutect2, varscan2
- LOXHD1 | c.4957G>A p.G1653R | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374897301; ClinVar: uncertain significance; called by mutect2, varscan2
- LPXN | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 26/375 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as rs370781907; called by muse, mutect2
- LRP1 | c.6832A>G p.I2278V | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs764383771; called by muse, mutect2, varscan2
- LRP1B | c.13316T>G p.I4439S | Missense Mutation (SNP) | VAF 55/227 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.039); catalogued as rs1324564113; called by muse, mutect2, varscan2
- LRRC31 | c.1624del p.R542Efs*37 | Frame Shift Del (DEL) | VAF 50/448 reads (11%) | catalogued as rs748577734; called by mutect2, pindel, varscan2
- LRRN3 | c.1471G>T p.G491W | Missense Mutation (SNP) | VAF 86/353 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV57817714; called by muse, mutect2, varscan2
- LTBP1 | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 40/491 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); catalogued as rs1036967060; called by muse, mutect2
- MAD2L2 | c.425del p.P142Qfs*45 | Frame Shift Del (DEL) | VAF 45/279 reads (16%) | catalogued as COSV99336009; called by mutect2, pindel, varscan2
- MADD | c.2146G>A p.G716R | Missense Mutation (SNP) | VAF 39/371 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.569); catalogued as rs773311660; called by muse, mutect2, varscan2
- MAEA | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 18/514 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as rs1336542514; called by muse, mutect2
- MAGEA12 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.547); catalogued as COSV63294229, COSV63294317; called by muse, mutect2
- MAP4K1 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 61/354 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as rs1179878816; called by muse, mutect2, varscan2
- MAP4K4 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1191731616; called by muse, mutect2
- MAPK8IP3 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 63/311 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767997804, COSV51721294; called by muse, mutect2, varscan2
- MAPKBP1 | c.4153T>G p.L1385V (on ENST00000456763 / NM_001128608.2; = p.L1379V on NM_014994.3) | Missense Mutation (SNP) | VAF 24/512 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV52967635; called by muse, mutect2
- MB | c.48del p.K17Rfs*34 | Frame Shift Del (DEL) | VAF 90/456 reads (20%) | catalogued as rs1248087242; called by mutect2, pindel, varscan2
- MBIP | c.257dup p.L86Ffs*9 | Frame Shift Ins (INS) | VAF 20/177 reads (11%) | catalogued as rs1358339986; called by pindel, varscan2
- MDGA2 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.691); catalogued as rs1339554778, COSV67807420; called by muse, mutect2
- MGAT1 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 85/400 reads (21%) | PolyPhen probably damaging (0.992); catalogued as rs778312623; called by muse, mutect2, varscan2
- MIDEAS | c.400T>C p.W134R | Missense Mutation (SNP) | VAF 16/492 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1278507526; called by muse, mutect2
- MINK1 | c.2378G>A p.R793H | Missense Mutation (SNP) | VAF 37/348 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs779881021, COSV53419351; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2050C>T p.R684* | Nonsense Mutation (SNP) | VAF 37/359 reads (10%) | catalogued as rs1208163796, COSV64054552; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs779304295; called by muse, varscan2
- MPHOSPH9 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 54/384 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.703); catalogued as rs369646331; called by muse, mutect2, varscan2
- MPRIP | c.2399C>T p.S800L | Missense Mutation (SNP) | VAF 29/301 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs1474101180, COSV57925618; called by muse, mutect2, varscan2
- MRTFA | c.2995G>A p.V999M | Missense Mutation (SNP) | VAF 98/476 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as rs775773947; called by muse, mutect2, varscan2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 31/250 reads (12%) | catalogued as rs767880823; called by mutect2, varscan2
- MTPN | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.934); catalogued as rs1423921992, COSV101262927, COSV67599324; called by muse, mutect2, varscan2
- MUC16 | c.6415A>G p.S2139G | Missense Mutation (SNP) | VAF 52/361 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV101200590, COSV101201741; called by muse, mutect2, varscan2
- MYEOV | c.905T>A p.L302H | Missense Mutation (SNP) | VAF 46/316 reads (15%) | PolyPhen benign (0.184); catalogued as rs770606307, COSV58293651; called by mutect2, varscan2
- MYF5 | c.72del p.E25Rfs*72 | Frame Shift Del (DEL) | VAF 65/431 reads (15%) | catalogued as COSV57355173; called by mutect2, pindel, varscan2
- MYH4 | c.947T>A p.V316D | Missense Mutation (SNP) | VAF 66/315 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55116766; called by muse, mutect2, varscan2
- MYH7B | c.2934G>T p.E978D | Missense Mutation (SNP) | VAF 95/447 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1430123475; called by muse, mutect2, varscan2
- MYL3 | c.10A>C p.K4Q | Missense Mutation (SNP) | VAF 55/272 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.918); catalogued as rs1404760917; called by muse, mutect2, varscan2
- NAV2 | c.6913C>T p.R2305W (on ENST00000396087 / NM_001244963.2; = p.R2246W on NM_145117.5) | Missense Mutation (SNP) | VAF 42/545 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs142419246; called by muse, mutect2
- NBEA | c.1647A>C p.K549N | Missense Mutation (SNP) | VAF 27/286 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV59783933, COSV59810805; called by muse, mutect2
- NEXN | c.196_197dup p.W67Nfs*25 | Frame Shift Ins (INS) | VAF 36/202 reads (18%) | catalogued as rs750492151; called by mutect2, varscan2
- NF1 | c.7458-1G>T p.X2486_splice (on ENST00000358273 / NM_001042492.3; = p.X2465_splice on NM_000267.3) | Splice Site (SNP) | VAF 22/185 reads (12%) | catalogued as CS000890, COSV62208209; called by mutect2, varscan2
- NFATC1 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 77/511 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1242324944; called by muse, mutect2, varscan2
- NLGN4X | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 97/690 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220178708, COSV52006855, COSV99319329, COSV99321108; called by muse, mutect2, varscan2
- NOL4 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs759309117, COSV52337464; called by muse, mutect2
- NOMO2 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 90/438 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as COSV57918589; called by muse, mutect2, varscan2
- NPAP1 | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 103/440 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs754535356; called by muse, mutect2, varscan2
- NPEPL1 | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 73/433 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.528); catalogued as rs749200060; called by muse, mutect2, varscan2
- NSDHL | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 78/448 reads (17%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs200748828, COSV64745148; called by muse, mutect2, varscan2
- NUB1 | c.990del p.K330Nfs*2 | Frame Shift Del (DEL) | VAF 64/380 reads (17%) | catalogued as rs760102115; called by mutect2, varscan2
- NUDCD1 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 60/374 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs765531808; called by muse, mutect2, varscan2
- NUFIP2 | c.670del p.R224Gfs*16 | Frame Shift Del (DEL) | VAF 87/473 reads (18%) | catalogued as rs772197760; called by mutect2, pindel, varscan2
- OPCML | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 56/368 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs374001465; called by muse, mutect2, varscan2
- OTOA | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 43/445 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759241745; called by muse, mutect2
- OTUD7A | c.706A>G p.M236V | Missense Mutation (SNP) | VAF 40/434 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs913728838; called by muse, mutect2
- P3H2 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 45/379 reads (12%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs1310957916; called by muse, mutect2, varscan2
- PABPC4 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 84/429 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100865406; called by muse, mutect2, varscan2
- PARVB | c.695T>C p.M232T | Missense Mutation (SNP) | VAF 47/400 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs775203649; called by muse, mutect2, varscan2
- PCDH8 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 50/383 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs772666214, COSV100132076, COSV58813701; called by muse, mutect2, varscan2
- PCDHA10 | c.1720G>A p.G574S | Missense Mutation (SNP) | VAF 86/356 reads (24%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV56514902; called by muse, mutect2, varscan2
- PCDHA8 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 38/453 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65327302; called by muse, mutect2
- PCDHAC2 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 58/313 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1554228636; called by muse, mutect2, varscan2
- PGAP1 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 48/303 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100698152; called by muse, mutect2, varscan2
- PHLDB1 | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 26/462 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV61879576; called by muse, mutect2
- PIBF1 | c.1533del p.K511Nfs*17 | Frame Shift Del (DEL) | VAF 30/313 reads (10%) | catalogued as COSV100411403; called by mutect2, pindel
- PIEZO1 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 71/379 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs866830948; called by muse, mutect2, varscan2
- PIK3CA | c.334A>T p.I112F | Missense Mutation (SNP) | VAF 15/235 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV55908000; called by muse, mutect2
- PITPNM2 | c.3221A>G p.H1074R | Missense Mutation (SNP) | VAF 44/488 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs767185068; called by muse, mutect2
- PIWIL4 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs772344895, COSV54408547; called by muse, mutect2, varscan2
- PKD2L2 | c.116del p.L39* | Frame Shift Del (DEL) | VAF 29/173 reads (17%) | catalogued as rs1406261366; called by mutect2, pindel, varscan2
- PLEC | c.5950C>T p.R1984W (on ENST00000322810 / NM_201380.4; = p.R1874W on NM_000445.5) | Missense Mutation (SNP) | VAF 25/625 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1421391265, COSV59681069; called by muse, mutect2
- PLEKHM1 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 133/661 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs771699086; called by muse, mutect2, varscan2
- PLK3 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.818); catalogued as rs146191329; called by muse, mutect2, varscan2
- PLSCR4 | c.719A>C p.K240T | Missense Mutation (SNP) | VAF 74/376 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs778979229; called by muse, mutect2, varscan2
- PLXNB1 | c.2960G>A p.S987N | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.532); catalogued as rs142167894; called by muse, mutect2
- PMF1 | c.577_578del p.E193Tfs*12 | Frame Shift Del (DEL) | VAF 38/340 reads (11%) | catalogued as rs755675418; called by pindel, varscan2
- POU4F2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 82/446 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV55584205; called by muse, mutect2, varscan2
- PPL | c.3599G>A p.R1200Q | Missense Mutation (SNP) | VAF 63/456 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs150446268, COSV52169941; called by muse, mutect2, varscan2
- PPL | c.1394+1G>A p.X465_splice | Splice Site (SNP) | VAF 19/277 reads (7%) | catalogued as rs1421162398; called by muse, mutect2
- PPP1R12A | c.1619del p.N540Ifs*23 | Frame Shift Del (DEL) | VAF 25/173 reads (14%) | catalogued as rs776166170; called by mutect2, varscan2
- PPP1R16B | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55384180; called by muse, mutect2, varscan2
- PPP1R18 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 148/680 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.116); catalogued as COSV51294819; called by muse, varscan2
- PPP1R3F | c.336del p.Y114Tfs*58 | Frame Shift Del (DEL) | VAF 64/590 reads (11%) | catalogued as rs1557118692; called by mutect2, pindel, varscan2
- PPP4R4 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 64/320 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs772495135, COSV58555668; called by muse, mutect2, varscan2
- PROP1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 68/316 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.099); catalogued as rs748484817, COSV57644868; called by muse, varscan2
- PRR16 | c.257G>A p.G86D (on ENST00000407149 / NM_001300783.2; = p.G63D on NM_016644.2) | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV101087712; called by muse, mutect2
- PRSS57 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 59/271 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as rs372754995; called by muse, mutect2, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 30/123 reads (24%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PSMD12 | c.224A>G p.Y75C | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.76); catalogued as rs756797479; called by muse, mutect2
- PTPRB | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 53/452 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs182023786; called by muse, mutect2, varscan2
- PUF60 | c.1288C>T p.R430W (on ENST00000526683 / NM_001362896.2; = p.R413W on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/726 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as rs759998258; called by muse, mutect2
- RBM10 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 114/541 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV61311633, COSV61313175, COSV61313298; called by muse, mutect2, varscan2
- RBMXL2 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 51/368 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs745383651; called by muse, mutect2, varscan2
- RBSN | c.1409T>C p.I470T | Missense Mutation (SNP) | VAF 43/398 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs767867391; called by muse, mutect2, varscan2
- RELA | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 64/368 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.091); catalogued as rs138794116; called by muse, mutect2, varscan2
- RERE | c.3611G>A p.R1204Q | Missense Mutation (SNP) | VAF 68/334 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.865); catalogued as rs1307287064, COSV100557639; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 58/226 reads (26%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RHOXF2 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 73/890 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as rs1254306506; called by muse, mutect2
- RIMS2 | c.3014C>A p.P1005H (on ENST00000666250 / NM_001348490.2; = p.P813H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.821); catalogued as COSV51736644; called by mutect2, varscan2
- RNASE13 | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 37/423 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs759129007; called by muse, mutect2
- RNF6 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 53/404 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1318922119; called by muse, mutect2, varscan2
- ROBO3 | c.571del p.R191Afs*31 | Frame Shift Del (DEL) | VAF 94/398 reads (24%) | catalogued as rs756837590; ClinVar: uncertain significance; called by mutect2, varscan2
- RPL26L1 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV54199689; called by muse, mutect2, varscan2
- RPL6 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs756136287; called by muse, mutect2, varscan2
- RPS6KA6 | c.327del p.A110Pfs*3 | Frame Shift Del (DEL) | VAF 40/274 reads (15%) | catalogued as rs756096568; called by pindel, varscan2
- RYR3 | c.3200G>A p.S1067N | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.314); catalogued as rs986030044; called by muse, mutect2, varscan2
- SDK1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 63/368 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs199853513; called by muse, mutect2, varscan2
- SDK2 | c.5848G>A p.V1950M | Missense Mutation (SNP) | VAF 40/500 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs980554263; called by muse, mutect2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 76/324 reads (23%) | catalogued as rs768388757; called by mutect2, varscan2
- SERTAD4 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 63/433 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369120586, COSV65399059; called by muse, mutect2, varscan2
- SFPQ | c.1831C>T p.R611* | Nonsense Mutation (SNP) | VAF 39/220 reads (18%) | catalogued as rs774720675, COSV61758691; called by muse, mutect2, varscan2
- SH3BGRL2 | c.249dup p.E84* | Frame Shift Ins (INS) | VAF 30/236 reads (13%) | catalogued as rs771667298; called by mutect2, varscan2
- SH3BP2 | c.823del p.R275Efs*3 | Frame Shift Del (DEL) | VAF 92/528 reads (17%) | catalogued as rs776466609, COSV62555238; called by pindel, varscan2
- SH3GL1 | c.912G>A p.P304= | Splice Region (SNP) | VAF 12/230 reads (5%) | catalogued as rs976125279; called by muse, mutect2
- SKAP1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 87/415 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs1273505806, COSV61144312; called by muse, mutect2, varscan2
- SLC12A1 | c.66A>C p.Q22H | Missense Mutation (SNP) | VAF 67/291 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV100372462; called by muse, mutect2, varscan2
- SLC20A2 | c.712A>G p.M238V | Missense Mutation (SNP) | VAF 34/401 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs1308896170; called by muse, mutect2
- SLC24A4 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 52/326 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs555903099, COSV54114906; called by muse, mutect2, varscan2
- SLC26A3 | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs780439320; called by muse, mutect2, varscan2
- SLC27A5 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 69/464 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.37); catalogued as rs750206701; called by muse, mutect2, varscan2
- SLC35F5 | c.1117C>T p.L373F | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs1283997587; called by muse, mutect2, varscan2
- SLC39A5 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 72/398 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751353753; called by muse, mutect2, varscan2
- SLC5A5 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 98/404 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs1304927206, COSV99715312; called by muse, mutect2, varscan2
- SLC6A18 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 21/312 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs376134763; called by muse, mutect2
- SLFN11 | c.1508del p.G503Afs*15 | Frame Shift Del (DEL) | VAF 23/165 reads (14%) | catalogued as rs1006801410; called by mutect2, pindel, varscan2
- SLMAP | c.1147G>A p.V383I (on ENST00000428312 / NM_001377924.1; = p.V404I on NM_007159.5) | Missense Mutation (SNP) | VAF 58/352 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs751946618; called by muse, mutect2, varscan2
- SLX4 | c.3028G>A p.A1010T | Missense Mutation (SNP) | VAF 88/497 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868176090; called by muse, mutect2, varscan2
- SMAP1 | c.613del p.S205Vfs*15 (on ENST00000370455 / NM_001044305.3; = p.S178Vfs*15 on NM_021940.5) | Frame Shift Del (DEL) | VAF 33/303 reads (11%) | catalogued as rs766085867, COSV100391091; called by mutect2, pindel, varscan2
- SMAP2 | c.773T>C p.I258T | Missense Mutation (SNP) | VAF 66/335 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs759635939; called by muse, mutect2, varscan2
- SMARCAD1 | c.1040del p.N347Mfs*24 | Frame Shift Del (DEL) | VAF 58/250 reads (23%) | catalogued as rs754697669; called by mutect2, varscan2
- SMPD4 | c.1505C>T p.A502V (on ENST00000409031 / NM_017951.4; = p.A473V on NM_017751.4) | Missense Mutation (SNP) | VAF 69/386 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs142376219; called by muse, mutect2, varscan2
- SPAG17 | c.3618A>C p.E1206D | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.932); catalogued as COSV60457494; called by muse, mutect2, varscan2
- SPATA20 | c.1784C>T p.A595V (on ENST00000356488 / NM_001258372.1; = p.A611V on NM_022827.4) | Missense Mutation (SNP) | VAF 92/455 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs763860836, COSV50066136; called by muse, mutect2, varscan2
- SPEF2 | c.2657del p.K886Rfs*8 | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | catalogued as rs750890082; called by mutect2, varscan2
- SPSB3 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 50/427 reads (12%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs756665663; called by muse, mutect2, varscan2
- SPTLC3 | c.1114A>C p.S372R | Missense Mutation (SNP) | VAF 19/348 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100982890, COSV65464481; called by muse, mutect2
- SRF | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 15/354 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs866274117; called by muse, mutect2
- SRGAP2 | c.2138C>T p.T713I (on ENST00000624873 / NM_001170637.4; = p.T714I on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/337 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1553375445; called by muse, mutect2, varscan2
- STARD3 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 55/288 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs1334870489; called by muse, mutect2, varscan2
- STARD8 | c.2618del p.P873Qfs*28 | Frame Shift Del (DEL) | VAF 73/536 reads (14%) | catalogued as rs761897392; called by mutect2, pindel, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 81/427 reads (19%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SYCP1 | c.2792del p.K931Rfs*6 | Frame Shift Del (DEL) | VAF 41/246 reads (17%) | catalogued as COSV101050748; called by mutect2, pindel, varscan2
- SYT6 | c.971G>A p.R324H (on ENST00000610222 / NM_001366225.1; = p.R239H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/419 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs200072587, COSV65775348; called by muse, mutect2, varscan2
- TARS3 | c.167A>C p.Q56P | Missense Mutation (SNP) | VAF 96/492 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.133); catalogued as COSV60108354; called by muse, varscan2
- TASOR2 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV60167590; called by muse, mutect2, varscan2
- TBC1D4 | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 50/404 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.793); catalogued as COSV66488789; called by muse, varscan2
- TC2N | c.855+1G>A p.X285_splice | Splice Site (SNP) | VAF 43/224 reads (19%) | catalogued as rs776919133, COSV61746961; called by muse, varscan2
- TCEAL4 | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 81/426 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs1027101661; called by muse, mutect2, varscan2
- TCF3 | c.878_880del p.F293del | In Frame Del (DEL) | VAF 98/467 reads (21%) | catalogued as rs748560717; called by mutect2, pindel, varscan2
- TESPA1 | c.292T>G p.L98V | Missense Mutation (SNP) | VAF 75/296 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57260296; called by muse, mutect2, varscan2
- TG | c.3406C>T p.R1136W | Missense Mutation (SNP) | VAF 45/353 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); catalogued as rs116642273; called by muse, mutect2, varscan2
- TGIF2LX | c.434A>T p.K145M | Missense Mutation (SNP) | VAF 144/668 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV52213774, COSV52213806; called by muse, mutect2, varscan2
- THBS4 | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs773151425; called by muse, mutect2, varscan2
- THEMIS2 | c.1652dup p.P552Tfs*5 | Frame Shift Ins (INS) | VAF 45/318 reads (14%) | catalogued as rs750840849; called by mutect2, varscan2
- TIAM1 | c.1442G>A p.G481D | Missense Mutation (SNP) | VAF 33/310 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200132537; called by muse, mutect2, varscan2
- TIMM17B | c.212del p.G71Afs*28 | Frame Shift Del (DEL) | VAF 46/303 reads (15%) | catalogued as rs782500597; called by mutect2, varscan2
- TMEM104 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1352939629; called by muse, mutect2
- TMEM179 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 50/500 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs958141098; called by muse, mutect2
- TMEM187 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 98/585 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs267606396, COSV100890203; called by muse, mutect2, varscan2
- TMEM63C | c.473A>C p.N158T | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100029319; called by muse, mutect2, varscan2
- TNK2 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 73/361 reads (20%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.923); catalogued as rs773644614, COSV57368996; called by muse, mutect2, varscan2
- TNN | c.3103G>A p.A1035T | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs548328539, COSV53432986; called by muse, mutect2, varscan2
- TNPO1 | c.2530del p.C844Vfs*45 | Frame Shift Del (DEL) | VAF 24/201 reads (12%) | catalogued as rs757314136; called by mutect2, pindel, varscan2
- TOMM40 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 56/323 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs984799309; called by muse, mutect2, varscan2
- TONSL | c.3910C>T p.R1304W | Missense Mutation (SNP) | VAF 81/460 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1032777372; called by muse, mutect2, varscan2
- TOR1AIP1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 25/343 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs534816625; ClinVar: uncertain significance; called by muse, mutect2
- TRAP1 | c.1221G>C p.E407D | Missense Mutation (SNP) | VAF 84/419 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1182378432, COSV55914490; called by muse, mutect2, varscan2
- TRIB2 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 78/368 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs376273712; called by muse, mutect2, varscan2
- TRMT10B | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 56/303 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs753380610, COSV53049723; called by muse, mutect2, varscan2
- TRMT6 | c.458del p.K153Nfs*9 | Frame Shift Del (DEL) | VAF 32/118 reads (27%) | catalogued as rs780358338; called by mutect2, varscan2
- TRPC1 | c.1394T>C p.L465P (on ENST00000476941 / NM_001251845.2; = p.L431P on NM_003304.4) | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1466855986; called by muse, mutect2
- TRPM1 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 63/358 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs534221059, COSV56638839; called by muse, mutect2, varscan2
- TRPM4 | c.3584G>A p.R1195H | Missense Mutation (SNP) | VAF 91/486 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1295618759; called by muse, mutect2, varscan2
- TRPV5 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 111/492 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs779621537, COSV54685314; called by muse, varscan2
- TSEN2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 98/417 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as rs142418832; called by muse, mutect2, varscan2
- TSNARE1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 92/565 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.997); catalogued as rs776111122, COSV56176634; called by muse, mutect2, varscan2
- TTC6 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 95/380 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.149); catalogued as rs896392930; called by muse, mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 58/323 reads (18%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTK | c.575dup p.Q193Afs*33 | Frame Shift Ins (INS) | VAF 33/299 reads (11%) | catalogued as rs756799506; called by mutect2, varscan2
- TTN | c.82843G>A p.V27615M (on ENST00000591111; = p.V20191M on NM_003319.4) | Missense Mutation (SNP) | VAF 70/416 reads (17%) | PolyPhen probably damaging (0.962); catalogued as rs1486415519, COSV100631983; called by muse, mutect2, varscan2
- TUBB1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 44/332 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.096); catalogued as COSV99413913; called by muse, mutect2, varscan2
- UBALD2 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.731); catalogued as rs545682018; called by muse, mutect2, varscan2
- UBE4B | c.3115G>A p.D1039N (on ENST00000343090 / NM_001105562.3; = p.D910N on NM_006048.5) | Missense Mutation (SNP) | VAF 23/396 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1402759807; called by muse, mutect2
- UGP2 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1351745580, COSV61427862; called by muse, mutect2, varscan2
- USP19 | c.3634C>T p.R1212C | Missense Mutation (SNP) | VAF 17/384 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866366361; called by muse, mutect2
- VEZT | c.220del p.S74Lfs*38 | Frame Shift Del (DEL) | VAF 31/245 reads (13%) | catalogued as rs748321397; called by mutect2, varscan2
- VILL | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 47/338 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs141085988; called by muse, mutect2, varscan2
- VNN1 | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 38/393 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs202106128; called by muse, varscan2
- WDFY4 | c.6227C>A p.P2076Q | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs771207501, COSV55425433; called by muse, varscan2
- WDR17 | c.2795A>G p.D932G | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as rs1487895549; called by muse, mutect2
- WDR75 | c.1378A>G p.T460A | Missense Mutation (SNP) | VAF 59/321 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.197); catalogued as rs1215177494; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 43/225 reads (19%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WHRN | c.2485G>A p.A829T | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs139597771; called by muse, varscan2
- WHRN | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as rs375229693; called by muse, mutect2, varscan2
- WNT6 | c.909del p.G304Afs*46 | Frame Shift Del (DEL) | VAF 114/589 reads (19%) | catalogued as rs779769070, COSV52110061; called by mutect2, pindel, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 104/410 reads (25%) | catalogued as rs779864368; called by mutect2, varscan2
- ZAP70 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 26/484 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs1313032320, COSV53856241; called by muse, mutect2
- ZC3H18 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 71/511 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); catalogued as rs749996866; called by muse, mutect2, varscan2
- ZDHHC3 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 89/452 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs1007580809; called by muse, mutect2, varscan2
- ZDHHC8 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as rs1262913417; called by muse, mutect2, varscan2
- ZFAND4 | c.1871del p.L624Cfs*8 | Frame Shift Del (DEL) | VAF 42/203 reads (21%) | catalogued as rs748928705, COSV99047996; called by mutect2, pindel, varscan2
- ZFAT | c.3325G>A p.A1109T | Missense Mutation (SNP) | VAF 66/432 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs762566183; called by muse, mutect2, varscan2
- ZFPM2 | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 82/465 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65875245; called by muse, mutect2, varscan2
- ZFYVE1 | c.2186G>A p.S729N | Missense Mutation (SNP) | VAF 91/469 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1301507416; called by muse, mutect2, varscan2
- ZIM3 | c.1150del p.I384Sfs*49 | Frame Shift Del (DEL) | VAF 54/342 reads (16%) | catalogued as rs750173990; called by pindel, varscan2
- ZMYM3 | c.1757del p.G586Afs*4 | Frame Shift Del (DEL) | VAF 48/466 reads (10%) | catalogued as COSV100077374; called by mutect2, pindel
- ZNF142 | c.5396A>G p.H1799R (on ENST00000411696 / NM_001379660.1; = p.H1599R on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/527 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs753180361, COSV68742831; called by muse, mutect2
- ZNF257 | c.371A>C p.K124T | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV101448109; called by muse, mutect2, varscan2
- ZNF257 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs751324442, COSV101447992; called by muse, mutect2, varscan2
- ZNF462 | c.2690A>C p.N897T | Missense Mutation (SNP) | VAF 107/477 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as rs761675707; called by muse, mutect2, varscan2
- ZNF497 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 103/403 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV99568257; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 50/243 reads (21%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF544 | c.1802A>G p.E601G | Missense Mutation (SNP) | VAF 41/500 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs1468089767; called by muse, mutect2
- ZNF628 | c.2731del p.D911Mfs*29 | Frame Shift Del (DEL) | VAF 86/536 reads (16%) | catalogued as COSV99219855; called by mutect2, pindel, varscan2
- ZNF717 | c.2030T>C p.V677A | Missense Mutation (SNP) | VAF 42/600 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV68866188; called by muse, mutect2
- ZNF85 | c.197A>C p.K66T | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV56022296; called by muse, mutect2, varscan2
- ZNF878 | c.507del p.K169Nfs*44 | Frame Shift Del (DEL) | VAF 79/402 reads (20%) | catalogued as rs773648883, COSV72155908; called by mutect2, pindel, varscan2
- ZRANB1 | c.1976del p.G659Efs*22 | Frame Shift Del (DEL) | VAF 101/514 reads (20%) | catalogued as rs34415074; called by mutect2, pindel, varscan2
- ZSCAN5A | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 88/408 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs777612921, COSV54227094; called by muse, mutect2, varscan2
- ABCA7 | c.791-1G>T p.X264_splice | Splice Site (SNP) | VAF 65/352 reads (18%) | called by muse, mutect2, varscan2
- ABCC3 | c.3218C>G p.S1073C | Missense Mutation (SNP) | VAF 88/428 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- AC004922.1 | c.1182del p.E395Rfs*6 | Frame Shift Del (DEL) | VAF 47/251 reads (19%) | called by mutect2, pindel, varscan2
- ACRBP | c.684G>T p.E228D | Missense Mutation (SNP) | VAF 57/484 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ACVR2A | c.36_39del p.F12Lfs*61 | Frame Shift Del (DEL) | VAF 45/266 reads (17%) | called by pindel, varscan2
- ACVR2A | c.602dup p.R202Kfs*12 | Frame Shift Ins (INS) | VAF 58/343 reads (17%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.3224T>A p.F1075Y | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- ADAMTS5 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 111/523 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1712A>T p.K571M | Missense Mutation (SNP) | VAF 40/439 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ADCY10 | c.4609G>A p.A1537T | Missense Mutation (SNP) | VAF 38/400 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADCY6 | c.1336T>C p.C446R | Missense Mutation (SNP) | VAF 33/426 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRE5 | c.2096C>A p.P699H (on ENST00000242786 / NM_078481.4; = p.P606H on NM_001784.5) | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL2 | c.3571C>A p.L1191I | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ADRA1D | c.215C>G p.P72R | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADRA2B | c.950T>C p.V317A | Missense Mutation (SNP) | VAF 58/482 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, varscan2
- AFAP1L1 | c.915G>T p.E305D | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AFF2 | c.1213T>C p.W405R | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AHDC1 | c.1507A>G p.S503G | Missense Mutation (SNP) | VAF 24/480 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.009); called by muse, mutect2
- ALDH1A3 | c.409T>G p.C137G | Missense Mutation (SNP) | VAF 19/410 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.397); called by muse, mutect2
- ALKAL2 | c.74del p.G25Afs*67 | Frame Shift Del (DEL) | VAF 114/403 reads (28%) | called by mutect2, pindel, varscan2
- ANKRD18A | c.1135del p.M379* | Frame Shift Del (DEL) | VAF 34/280 reads (12%) | called by mutect2, varscan2
- ANKRD50 | c.2592A>C p.E864D | Missense Mutation (SNP) | VAF 18/434 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2
- APBB1 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 103/378 reads (27%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.935); called by muse, varscan2
- APC | c.4778dup p.P1594Afs*38 | Frame Shift Ins (INS) | VAF 84/424 reads (20%) | called by mutect2, pindel, varscan2
- APC2 | c.4948C>T p.R1650C | Missense Mutation (SNP) | VAF 59/555 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ARHGAP5 | c.2676dup p.E893* | Frame Shift Ins (INS) | VAF 46/314 reads (15%) | called by mutect2, varscan2
- ARHGEF10 | c.1126A>G p.R376G (on ENST00000398564; = p.R351G on NM_014629.4) | Missense Mutation (SNP) | VAF 41/395 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- ARHGEF17 | c.4460C>T p.A1487V | Missense Mutation (SNP) | VAF 58/341 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGEF18 | c.2219C>T p.T740I (on ENST00000359920 / NM_001130955.2; = p.T636I on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- ARHGEF9 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 74/428 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARID1A | c.4724dup p.P1576Tfs*27 | Frame Shift Ins (INS) | VAF 42/253 reads (17%) | called by mutect2, pindel, varscan2
- ARID1B | c.1987_1989del p.S664del | In Frame Del (DEL) | VAF 17/176 reads (10%) | called by pindel, varscan2
- ARL3 | c.167T>A p.V56E | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARSF | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ASB12 | c.301A>G p.S101G | Missense Mutation (SNP) | VAF 56/658 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.894); called by muse, mutect2
- ASPM | c.6373G>A p.A2125T | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ATF7IP2 | c.1635G>T p.Q545H | Missense Mutation (SNP) | VAF 45/287 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ATG3 | c.393G>T p.K131N | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- ATP6AP2 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 48/387 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ATP8A2 | c.2726A>T p.E909V | Missense Mutation (SNP) | VAF 91/395 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATXN7L2 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 81/463 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BCL11A | c.976del p.L326Sfs*61 (on ENST00000335712 / NM_001365609.1; = p.L360Sfs*61 on NM_018014.4) | Frame Shift Del (DEL) | VAF 64/246 reads (26%) | called by mutect2, varscan2
- BCLAF3 | c.1867A>G p.T623A (on ENST00000379682 / NM_001367774.1; = p.T594A on NM_198279.3) | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- BCO2 | c.922A>G p.K308E | Missense Mutation (SNP) | VAF 15/369 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- BEST1 | c.1721A>G p.Y574C | Missense Mutation (SNP) | VAF 100/471 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEX3 | c.253C>G p.Q85E | Missense Mutation (SNP) | VAF 92/479 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- BHLHE40 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 104/449 reads (23%) | called by muse, mutect2, varscan2
- BICRA | c.3602A>G p.Y1201C | Missense Mutation (SNP) | VAF 14/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- BIVM-ERCC5 | c.3535C>T p.L1179F | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BOC | c.3158-1G>T p.X1053_splice | Splice Site (SNP) | VAF 34/251 reads (14%) | called by muse, mutect2, varscan2
- BOP1 | c.968G>A p.S323N | Missense Mutation (SNP) | VAF 109/634 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BRD1 | c.1023C>A p.C341* | Nonsense Mutation (SNP) | VAF 53/438 reads (12%) | called by muse, mutect2, varscan2
- BRD9 | c.1301G>T p.S434I | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- BRDT | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- BST1 | c.881dup p.S295Kfs*74 | Frame Shift Ins (INS) | VAF 31/268 reads (12%) | called by mutect2, pindel, varscan2
- BUB1B | c.2156A>G p.Q719R | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2
- C16orf71 | c.365A>G p.D122G | Missense Mutation (SNP) | VAF 85/412 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C18orf63 | c.1018del p.M340Cfs*6 | Frame Shift Del (DEL) | VAF 54/312 reads (17%) | called by mutect2, varscan2
- C1QTNF4 | c.519del p.E174Sfs*74 | Frame Shift Del (DEL) | VAF 29/211 reads (14%) | called by mutect2, pindel, varscan2
- C2CD2L | c.292_293del p.F98Pfs*28 | Frame Shift Del (DEL) | VAF 70/401 reads (17%) | called by mutect2, pindel, varscan2
- C2orf16 | c.1899A>T p.E633D | Missense Mutation (SNP) | VAF 45/453 reads (10%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.73); called by muse, mutect2
- C4orf54 | c.928G>T p.G310C | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.337); called by muse, mutect2
- CA11 | c.93dup p.E32Rfs*9 | Frame Shift Ins (INS) | VAF 47/342 reads (14%) | called by mutect2, pindel, varscan2
- CABLES1 | c.1514A>C p.K505T (on ENST00000256925 / NM_001100619.2; = p.K240T on NM_138375.2) | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CACHD1 | c.274del p.I92Sfs*19 | Frame Shift Del (DEL) | VAF 29/281 reads (10%) | called by mutect2, pindel, varscan2
- CACNA1C | c.1735G>T p.G579C | Missense Mutation (SNP) | VAF 40/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CACNB3 | c.1316C>A p.P439H | Missense Mutation (SNP) | VAF 54/476 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- CACNG7 | c.643del p.A215Pfs*40 | Frame Shift Del (DEL) | VAF 96/541 reads (18%) | called by mutect2, pindel, varscan2
- CAD | c.4293G>T p.K1431N | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CADPS | c.231del p.L78Cfs*20 | Frame Shift Del (DEL) | VAF 15/120 reads (13%) | called by mutect2, pindel, varscan2
- CALY | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 37/550 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CAT | c.1405G>T p.D469Y | Missense Mutation (SNP) | VAF 18/431 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2
- CATSPERE | c.927T>G p.S309R | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by mutect2, varscan2
- CBLC | c.1313del p.P438Hfs*17 | Frame Shift Del (DEL) | VAF 84/460 reads (18%) | called by mutect2, pindel, varscan2
- CCDC120 | c.765del p.S256Afs*19 | Frame Shift Del (DEL) | VAF 112/572 reads (20%) | called by mutect2, pindel, varscan2
- CCDC120 | c.1874A>G p.Y625C | Missense Mutation (SNP) | VAF 39/392 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CCDC8 | c.410G>T p.S137I | Missense Mutation (SNP) | VAF 98/439 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CDH26 | c.966dup p.H323Afs*3 | Frame Shift Ins (INS) | VAF 37/381 reads (10%) | called by mutect2, pindel, varscan2
- CDHR4 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 22/541 reads (4%) | called by muse, mutect2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 112/539 reads (21%) | called by mutect2, pindel, varscan2
- CEP295 | c.7054G>A p.A2352T | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- CEP41 | c.230_231del p.S77* | Frame Shift Del (DEL) | VAF 62/366 reads (17%) | called by pindel, varscan2
- CERS1 | c.803G>A p.S268N | Missense Mutation (SNP) | VAF 73/409 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CFAP65 | c.2149T>C p.F717L | Missense Mutation (SNP) | VAF 22/534 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- CFH | c.2234T>A p.V745E | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHAT | c.106T>C p.F36L | Missense Mutation (SNP) | VAF 81/412 reads (20%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD2 | c.3127T>C p.W1043R | Missense Mutation (SNP) | VAF 32/335 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CHD7 | c.8962del p.D2988Mfs*3 | Frame Shift Del (DEL) | VAF 67/411 reads (16%) | called by mutect2, pindel, varscan2
- CHST7 | c.1191_1192del p.L398Rfs*144 | Frame Shift Del (DEL) | VAF 90/516 reads (17%) | called by pindel, varscan2
- CILP | c.3168C>A p.N1056K | Missense Mutation (SNP) | VAF 59/481 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- CLCN7 | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CLEC12A | c.712T>C p.Y238H | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLPP | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 105/380 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN6 | c.2518G>C p.V840L | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- COL25A1 | c.1944G>A p.M648I | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.838); called by muse, mutect2
- COL9A3 | c.1258del p.Q420Rfs*113 | Frame Shift Del (DEL) | VAF 72/363 reads (20%) | called by mutect2, pindel, varscan2
- COQ10A | c.459A>C p.K153N | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); called by muse, mutect2
- CPSF1 | c.1203G>T p.Q401H | Missense Mutation (SNP) | VAF 46/425 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CSMD1 | c.4877G>A p.C1626Y (on ENST00000520002; = p.C1625Y on NM_033225.6) | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSTF3 | c.1877C>A p.P626H | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CTCF | c.962del p.P321Lfs*12 | Frame Shift Del (DEL) | VAF 70/337 reads (21%) | called by mutect2, pindel, varscan2
- CTNNA1 | c.2327T>C p.L776P | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CYLC1 | c.1589C>T p.T530I | Missense Mutation (SNP) | VAF 20/422 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.689); called by muse, mutect2
- CYLD | c.2165del p.N722Mfs*13 | Frame Shift Del (DEL) | VAF 36/259 reads (14%) | called by mutect2, varscan2
- CYP7A1 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 77/472 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DAGLB | c.1397A>G p.Y466C | Missense Mutation (SNP) | VAF 47/355 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DCLK1 | c.525G>T p.E175D | Missense Mutation (SNP) | VAF 47/365 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DCLK1 | c.73T>C p.S25P | Missense Mutation (SNP) | VAF 114/505 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DCP2 | c.136del p.Y46Tfs*17 | Frame Shift Del (DEL) | VAF 75/468 reads (16%) | called by mutect2, pindel, varscan2
- DGKA | c.1973G>T p.G658V | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHRS3 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 30/427 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DHX15 | c.2303T>C p.M768T | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DIP2A | c.3665del p.P1222Rfs*29 | Frame Shift Del (DEL) | VAF 37/320 reads (12%) | called by mutect2, pindel, varscan2
- DLG3 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 23/558 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.931); called by muse, mutect2
- DMRT1 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 32/375 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- DMTN | c.281del p.P94Hfs*137 | Frame Shift Del (DEL) | VAF 88/534 reads (16%) | called by mutect2, pindel, varscan2
- DOT1L | c.4396G>T p.G1466C | Missense Mutation (SNP) | VAF 56/440 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); called by mutect2, varscan2
- DRD5 | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2
- DRP2 | c.2420A>C p.K807T | Missense Mutation (SNP) | VAF 101/439 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DTNA | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.421); called by muse, mutect2
- DUSP18 | c.161T>G p.V54G | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DUSP8 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 95/448 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DYNC1H1 | c.6219del p.F2073Lfs*21 | Frame Shift Del (DEL) | VAF 26/211 reads (12%) | called by mutect2, pindel, varscan2
- DYRK1A | c.827T>C p.L276P | Missense Mutation (SNP) | VAF 67/400 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYRK2 | c.526T>C p.F176L (on ENST00000344096 / NM_006482.3; = p.F103L on NM_003583.4) | Missense Mutation (SNP) | VAF 33/362 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- EDF1 | c.81T>C p.A27= | Splice Region (SNP) | VAF 59/267 reads (22%) | called by muse, mutect2, varscan2
- EEF1AKNMT | c.460G>T p.G154C (on ENST00000361735 / NM_015935.5; = p.G68C on NM_014955.3) | Missense Mutation (SNP) | VAF 44/404 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- EGFLAM | c.2850dup p.S951Ifs*9 (on ENST00000354891 / NM_001205301.2; = p.S943Ifs*9 on NM_152403.4) | Frame Shift Ins (INS) | VAF 48/303 reads (16%) | called by mutect2, pindel, varscan2
- ELFN1 | c.941A>G p.E314G | Missense Mutation (SNP) | VAF 21/557 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); called by muse, mutect2
- ELP1 | c.2621C>T p.A874V | Missense Mutation (SNP) | VAF 14/379 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.404); called by muse, mutect2
- EPDR1 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 65/355 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA2 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 68/350 reads (19%) | called by mutect2, pindel, varscan2
- EPHA6 | c.2570del p.L857Cfs*24 (on ENST00000389672 / NM_001080448.3; = p.L249Cfs*24 on NM_173655.4) | Frame Shift Del (DEL) | VAF 67/320 reads (21%) | called by mutect2, pindel, varscan2
- EPHB6 | c.849del p.R284Gfs*12 | Frame Shift Del (DEL) | VAF 90/466 reads (19%) | called by mutect2, varscan2
- ERC1 | c.1867G>A p.A623T (on ENST00000360905 / NM_178040.4; = p.A595T on NM_178039.4) | Missense Mutation (SNP) | VAF 27/300 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.37); called by muse, mutect2
- ERICH3 | c.3005A>C p.E1002A | Missense Mutation (SNP) | VAF 76/428 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ESAM | c.47del p.L16Cfs*5 | Frame Shift Del (DEL) | VAF 66/370 reads (18%) | called by mutect2, pindel, varscan2
- ESRRB | c.863T>C p.I288T | Missense Mutation (SNP) | VAF 44/510 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.14); called by muse, mutect2
- ESRRB | c.1163G>T p.R388M | Missense Mutation (SNP) | VAF 63/305 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EVC2 | c.1390A>C p.K464Q | Missense Mutation (SNP) | VAF 86/380 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- EXPH5 | c.4483del p.M1495* | Frame Shift Del (DEL) | VAF 36/325 reads (11%) | called by mutect2, pindel, varscan2
- EXTL3 | c.1423A>G p.M475V | Missense Mutation (SNP) | VAF 48/510 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- F10 | c.593T>C p.I198T | Missense Mutation (SNP) | VAF 24/503 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- F5 | c.6563T>A p.V2188E | Missense Mutation (SNP) | VAF 41/325 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- F8 | c.4854G>T p.L1618F | Missense Mutation (SNP) | VAF 58/445 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- F9 | c.43A>G p.I15V | Missense Mutation (SNP) | VAF 45/389 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- FADS2 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FAM111B | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 63/348 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- FAM135A | c.4190C>A p.P1397H (on ENST00000370479 / NM_001351599.1; = p.P1184H on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/320 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- FAM83G | c.2408G>A p.S803N | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, mutect2
- FBF1 | c.1483G>T p.G495W (on ENST00000586717; = p.G509W on NM_001319193.1) | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- FBF1 | c.1022G>A p.G341E (on ENST00000586717; = p.G355E on NM_001319193.1) | Missense Mutation (SNP) | VAF 62/453 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FBXL19 | c.1214del p.P405Rfs*62 | Frame Shift Del (DEL) | VAF 116/605 reads (19%) | called by mutect2, pindel, varscan2
- FBXW10 | c.2082A>C p.K694N | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- FCSK | c.377del p.N126Tfs*9 | Frame Shift Del (DEL) | VAF 45/239 reads (19%) | called by mutect2, pindel, varscan2
- FDX2 | c.556dup p.H186Pfs*4 | Frame Shift Ins (INS) | VAF 46/313 reads (15%) | called by mutect2, pindel, varscan2
- FERMT2 | c.26C>A p.P9Q | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- FGFRL1 | c.1369del p.Q457Sfs*123 | Frame Shift Del (DEL) | VAF 104/544 reads (19%) | called by pindel, varscan2
- FGL1 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 81/317 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLCN | c.1723T>C p.S575P | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.093); called by muse, mutect2
- FLNA | c.6676T>C p.F2226L (on ENST00000369850 / NM_001110556.2; = p.F2218L on NM_001456.3) | Missense Mutation (SNP) | VAF 24/700 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- FLT4 | c.2947G>A p.A983T | Missense Mutation (SNP) | VAF 18/572 reads (3%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2
- FMOD | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 29/484 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- FRMPD4 | c.1693del p.E565Nfs*6 | Frame Shift Del (DEL) | VAF 100/485 reads (21%) | called by mutect2, pindel, varscan2
- FRYL | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.027); called by muse, mutect2
- FSCB | c.1370T>A p.F457Y | Missense Mutation (SNP) | VAF 75/364 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GABRA3 | c.736T>G p.L246V | Missense Mutation (SNP) | VAF 96/379 reads (25%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- GAS2 | c.324del p.F108Lfs*16 | Frame Shift Del (DEL) | VAF 44/384 reads (11%) | called by mutect2, varscan2
- GATA6 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 22/437 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- GCN1 | c.2684C>T p.P895L | Missense Mutation (SNP) | VAF 40/483 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- GJC1 | c.1132T>A p.S378T | Missense Mutation (SNP) | VAF 67/391 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- GNAZ | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 78/398 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- GP1BB | c.35T>G p.L12R | Missense Mutation (SNP) | VAF 59/277 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- GP5 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 16/423 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2
- GPR161 | c.634T>G p.F212V | Missense Mutation (SNP) | VAF 38/476 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- GPR20 | c.122T>C p.L41P | Missense Mutation (SNP) | VAF 85/648 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPRC5A | c.998del p.K333Rfs*20 | Frame Shift Del (DEL) | VAF 40/338 reads (12%) | called by mutect2, pindel, varscan2
- GRIP2 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 40/372 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GRM2 | c.2077A>G p.I693V | Missense Mutation (SNP) | VAF 77/461 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GUCY2C | c.2221dup p.I741Nfs*2 | Frame Shift Ins (INS) | VAF 44/221 reads (20%) | called by mutect2, varscan2
- HADH | c.711T>C p.G237= | Splice Region (SNP) | VAF 26/223 reads (12%) | called by muse, mutect2, varscan2
- HAS1 | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 104/469 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, varscan2
- HAUS6 | c.1589dup p.S530Rfs*2 | Frame Shift Ins (INS) | VAF 27/256 reads (11%) | called by mutect2, pindel, varscan2
- HDAC9 | c.377C>A p.P126H | Missense Mutation (SNP) | VAF 33/319 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HDGFL1 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, varscan2
- HDLBP | c.1406T>A p.V469E | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by mutect2, varscan2
- HEATR9 | c.1048A>G p.T350A | Missense Mutation (SNP) | VAF 26/507 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.034); called by muse, mutect2
- HECTD4 | c.10036C>T p.P3346S | Missense Mutation (SNP) | VAF 48/411 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HES7 | c.193T>C p.Y65H | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- HLA-DQB2 | c.99G>T p.K33N | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.098); called by mutect2, varscan2
- HMCN1 | c.2672T>G p.L891R | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.228); called by muse, mutect2
- HMCN1 | c.3407A>C p.K1136T | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HMGCS2 | c.1264dup p.S422Ffs*37 | Frame Shift Ins (INS) | VAF 48/276 reads (17%) | called by pindel, varscan2
- HNRNPA2B1 | c.527C>T p.T176I (on ENST00000354667 / NM_031243.3; = p.T164I on NM_002137.4) | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- HP1BP3 | c.1159del p.T387Pfs*86 | Frame Shift Del (DEL) | VAF 49/236 reads (21%) | called by mutect2, pindel, varscan2
- HS6ST3 | c.84del p.S29Pfs*103 | Frame Shift Del (DEL) | VAF 63/347 reads (18%) | called by mutect2, pindel, varscan2
- HYDIN | c.2541del p.K847Nfs*23 | Frame Shift Del (DEL) | VAF 19/120 reads (16%) | called by mutect2, varscan2
- IARS1 | c.2866G>T p.G956C | Missense Mutation (SNP) | VAF 69/302 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by mutect2, varscan2
- ICAM3 | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 56/367 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IDI2 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGDCC3 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- IGFN1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 63/363 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- IGSF10 | c.239T>G p.L80R | Missense Mutation (SNP) | VAF 52/697 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IK | c.38del p.L13Wfs*29 | Frame Shift Del (DEL) | VAF 58/335 reads (17%) | called by mutect2, pindel, varscan2
- IPO4 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 48/318 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRF2 | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 44/446 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ISX | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA1 | c.2438A>C p.K813T | Missense Mutation (SNP) | VAF 34/300 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ITGA1 | c.3385A>G p.I1129V | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ITGB7 | c.443A>G p.E148G | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.451); called by mutect2, varscan2
- ITIH5 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 15/482 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- ITK | c.1657A>G p.S553G | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- IWS1 | c.2004dup p.K669Qfs*6 | Frame Shift Ins (INS) | VAF 31/322 reads (10%) | called by mutect2, pindel, varscan2
- JAM3 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 59/315 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- JPH4 | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 77/417 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- JUNB | c.344del p.G115Vfs*35 | Frame Shift Del (DEL) | VAF 109/508 reads (21%) | called by mutect2, pindel, varscan2
- KCNA4 | c.1559T>C p.V520A | Missense Mutation (SNP) | VAF 86/430 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNF1 | c.1007T>C p.F336S | Missense Mutation (SNP) | VAF 24/489 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2
- KCNH3 | c.2270G>A p.G757D | Missense Mutation (SNP) | VAF 19/549 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0.129); called by muse, mutect2
- KCNS2 | c.833A>C p.N278T | Missense Mutation (SNP) | VAF 43/404 reads (11%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- KCNU1 | c.2464C>A p.L822I | Missense Mutation (SNP) | VAF 66/431 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- KDM2A | c.2443A>G p.I815V | Missense Mutation (SNP) | VAF 90/418 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, varscan2
- KIAA0895L | c.45del p.S16Afs*13 | Frame Shift Del (DEL) | VAF 58/373 reads (16%) | called by mutect2, varscan2
- KIAA1549L | c.3820A>G p.S1274G (on ENST00000321505; = p.S1571G on NM_012194.3) | Missense Mutation (SNP) | VAF 27/310 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- KIF17 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 40/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF21A | c.4808G>A p.C1603Y (on ENST00000361418 / NM_001378440.1; = p.C1590Y on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/492 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- KIFC3 | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 71/357 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KLK11 | c.379dup p.H127Pfs*16 (on ENST00000594768 / NM_144947.3; = p.H95Pfs*16 on NM_006853.3) | Frame Shift Ins (INS) | VAF 62/477 reads (13%) | called by mutect2, pindel, varscan2
- KRTAP20-1 | c.7T>C p.Y3H | Missense Mutation (SNP) | VAF 10/320 reads (3%) | PolyPhen possibly damaging (0.761); called by muse, mutect2
- KRTAP4-8 | c.250T>C p.C84R | Missense Mutation (SNP) | VAF 134/654 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, varscan2
- LAMA1 | c.3824C>A p.P1275Q | Missense Mutation (SNP) | VAF 75/357 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- LAMC1 | c.2188A>C p.S730R | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCT | c.3850G>T p.E1284* | Nonsense Mutation (SNP) | VAF 43/363 reads (12%) | called by muse, mutect2, varscan2
- LHCGR | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 77/340 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, varscan2
- LRRC14 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 17/488 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.09); called by muse, mutect2
- LRRC14B | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 68/335 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- LYL1 | c.162del p.R55Gfs*8 | Frame Shift Del (DEL) | VAF 102/527 reads (19%) | called by mutect2, pindel, varscan2
- LYPD1 | c.109T>C p.C37R | Missense Mutation (SNP) | VAF 62/360 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LYPLA2 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 75/336 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MAGEC1 | c.2200dup p.E734Gfs*28 | Frame Shift Ins (INS) | VAF 123/634 reads (19%) | called by mutect2, pindel, varscan2
- MAP3K15 | c.142A>C p.S48R | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT tolerated (0.47); called by muse, mutect2
- MAP3K15 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.51); called by muse, varscan2
- MAP3K2 | c.120del p.K40Nfs*29 | Frame Shift Del (DEL) | VAF 36/271 reads (13%) | called by mutect2, pindel, varscan2
- MAPK4 | c.1202C>T p.S401L | Missense Mutation (SNP) | VAF 105/484 reads (22%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MBOAT7 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 52/598 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- MCM8 | c.1482T>A p.D494E | Missense Mutation (SNP) | VAF 48/385 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- MDH1 | c.941A>G p.D314G | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- MDH1B | c.16A>G p.I6V | Missense Mutation (SNP) | VAF 63/342 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MDN1 | c.2695A>T p.R899* | Nonsense Mutation (SNP) | VAF 57/275 reads (21%) | called by muse, mutect2, varscan2
- MEA1 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 72/370 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED13 | c.1849T>G p.Y617D | Missense Mutation (SNP) | VAF 77/346 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- MEMO1 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- MFSD12 | c.581C>A p.S194* | Nonsense Mutation (SNP) | VAF 87/492 reads (18%) | called by muse, mutect2, varscan2
- MFSD6 | c.1497del p.F499Lfs*8 | Frame Shift Del (DEL) | VAF 52/336 reads (15%) | called by mutect2, pindel, varscan2
- MGAT3 | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 94/456 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- MICAL3 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- MICU2 | c.594del p.F198Lfs*7 | Frame Shift Del (DEL) | VAF 35/199 reads (18%) | called by mutect2, pindel, varscan2
- MIER2 | c.24del p.R9Gfs*111 | Frame Shift Del (DEL) | VAF 64/368 reads (17%) | called by mutect2, pindel, varscan2
- MOGS | c.1724C>A p.P575H | Missense Mutation (SNP) | VAF 92/395 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSX2 | c.639del p.K213Nfs*89 | Frame Shift Del (DEL) | VAF 88/477 reads (18%) | called by mutect2, pindel, varscan2
- MTSS1 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 60/367 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MUC22 | c.1606A>C p.T536P | Missense Mutation (SNP) | VAF 107/535 reads (20%) | SIFT tolerated (0.22); called by mutect2, varscan2
- MYADML2 | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 28/504 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); called by muse, mutect2
- MYBL2 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 26/381 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH13 | c.1369T>C p.Y457H | Missense Mutation (SNP) | VAF 16/566 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.062); called by muse, mutect2
- MYL10 | c.386T>C p.M129T | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO15B | c.2474dup p.I826Dfs*68 | Frame Shift Ins (INS) | VAF 40/369 reads (11%) | called by mutect2, pindel, varscan2
- MYO1B | c.2188del p.S730Afs*4 | Frame Shift Del (DEL) | VAF 44/356 reads (12%) | called by pindel, varscan2
- MYO3B | c.748A>T p.R250* | Nonsense Mutation (SNP) | VAF 30/162 reads (19%) | called by muse, mutect2, varscan2
- NBEA | c.3586T>G p.L1196V | Missense Mutation (SNP) | VAF 44/362 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NCEH1 | c.313del p.S105Afs*8 (on ENST00000538775; = p.S73Afs*8 on NM_020792.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 83/755 reads (11%) | called by mutect2, pindel, varscan2
- NCF2 | c.362G>A p.C121Y | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NCKAP1L | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 32/180 reads (18%) | called by muse, mutect2, varscan2
- NDUFA13 | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- NEB | c.6134A>G p.D2045G | Missense Mutation (SNP) | VAF 55/346 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NELFB | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 37/369 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- NFIC | c.1367del p.P456Lfs*36 (on ENST00000443272 / NM_001245002.2; = p.P447Lfs*36 on NM_205843.3) | Frame Shift Del (DEL) | VAF 131/465 reads (28%) | called by mutect2, pindel, varscan2
- NIN | c.5935C>T p.Q1979* (on ENST00000382041 / NM_182946.1; = p.Q1266* on NM_016350.4) | Nonsense Mutation (SNP) | VAF 102/384 reads (27%) | called by muse, mutect2, varscan2
- NKD2 | c.1307A>G p.H436R | Missense Mutation (SNP) | VAF 74/595 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- NKX2-1 | c.601A>T p.T201S | Missense Mutation (SNP) | VAF 93/495 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NLN | c.1771A>G p.N591D | Missense Mutation (SNP) | VAF 74/380 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRP11 | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 67/313 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NLRP7 | c.1192C>T p.L398F | Missense Mutation (SNP) | VAF 157/663 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NOTCH1 | c.3761C>T p.T1254I | Missense Mutation (SNP) | VAF 18/532 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2
- NOTCH2 | c.3337G>T p.G1113C | Missense Mutation (SNP) | VAF 25/288 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- NOTCH4 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 145/677 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- NOTCH4 | c.944T>A p.V315E | Missense Mutation (SNP) | VAF 143/533 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- NPHP3 | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- NPR1 | c.2135C>A p.P712H | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.125); called by muse, mutect2
- NRXN1 | c.2258G>A p.G753D | Missense Mutation (SNP) | VAF 30/511 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NRXN2 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 74/385 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- NSUN2 | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.311); called by muse, varscan2
- NT5C1A | c.859A>G p.S287G | Missense Mutation (SNP) | VAF 22/511 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2
- NUBP2 | c.17A>G p.E6G | Missense Mutation (SNP) | VAF 14/297 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- NUPR2 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2
- NUTM1 | c.2650G>A p.A884T | Missense Mutation (SNP) | VAF 38/548 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- OGA | c.1818A>C p.E606D | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- OR1R1P | c.700C>A p.R234S | Missense Mutation (SNP) | VAF 79/345 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- OR2L2 | c.584A>G p.E195G | Missense Mutation (SNP) | VAF 30/357 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- OR2T3 | c.353T>C p.F118S | Missense Mutation (SNP) | VAF 83/831 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- OR4S2 | c.10dup p.I4Nfs*6 | Frame Shift Ins (INS) | VAF 15/89 reads (17%) | called by mutect2, pindel, varscan2
- OR5AK2 | c.464A>T p.N155I | Missense Mutation (SNP) | VAF 32/413 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- OTOA | c.2081A>G p.Y694C (on ENST00000286149; = p.Y680C on NM_144672.4) | Missense Mutation (SNP) | VAF 18/357 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- OTUD7A | c.365G>A p.S122N | Missense Mutation (SNP) | VAF 87/469 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- P2RY6 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 40/552 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- PALLD | c.1903A>G p.T635A | Missense Mutation (SNP) | VAF 72/400 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PALMD | c.1523A>T p.E508V | Missense Mutation (SNP) | VAF 16/445 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PAPLN | c.2029del p.H677Ifs*125 (on ENST00000554301; = p.H650Ifs*125 on NM_173462.4) | Frame Shift Del (DEL) | VAF 45/316 reads (14%) | called by mutect2, pindel, varscan2
- PAPPA2 | c.5327A>G p.D1776G | Missense Mutation (SNP) | VAF 43/341 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- PARP12 | c.1489G>A p.G497S | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PCDHGA12 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 71/381 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- PCNT | c.1016del p.N339Tfs*4 | Frame Shift Del (DEL) | VAF 41/291 reads (14%) | called by mutect2, pindel, varscan2
- PCOLCE | c.176del p.P59Lfs*9 | Frame Shift Del (DEL) | VAF 60/318 reads (19%) | called by mutect2, pindel, varscan2
- PDPK1 | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 64/307 reads (21%) | called by muse, mutect2, varscan2
- PHACTR3 | c.21del p.R8Afs*52 | Frame Shift Del (DEL) | VAF 20/220 reads (9%) | called by mutect2, pindel
- PHRF1 | c.4415A>G p.Q1472R (on ENST00000264555 / NM_001286581.2; = p.Q1471R on NM_020901.4) | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- PIEZO1 | c.2991G>T p.E997D | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- PIGW | c.32T>C p.V11A | Missense Mutation (SNP) | VAF 73/330 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- PIGW | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 106/496 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by mutect2, varscan2
- PIK3C3 | c.1486T>C p.Y496H | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- PITPNM3 | c.2631G>T p.E877D | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PITPNM3 | c.1010C>A p.P337Q | Missense Mutation (SNP) | VAF 73/427 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- PKHD1L1 | c.1907C>T p.T636I | Missense Mutation (SNP) | VAF 59/381 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- PLEKHA7 | c.2870A>G p.K957R | Missense Mutation (SNP) | VAF 52/526 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2
- PLK5 | c.709del p.R237Gfs*40 | Frame Shift Del (DEL) | VAF 75/368 reads (20%) | called by mutect2, pindel, varscan2
- PLXNB2 | c.3608C>A p.P1203Q | Missense Mutation (SNP) | VAF 44/433 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLXNC1 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 93/512 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- PMFBP1 | c.2335G>T p.A779S (on ENST00000537465; = p.A774S on NM_031293.3) | Missense Mutation (SNP) | VAF 47/357 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PNKP | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PNMA8B | c.643A>C p.S215R | Missense Mutation (SNP) | VAF 30/556 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- POLG | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 20/601 reads (3%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); called by muse, mutect2
- PPP1R10 | c.2815del p.L939Cfs*109 | Frame Shift Del (DEL) | VAF 76/491 reads (15%) | called by mutect2, pindel, varscan2
- PPP1R9A | c.267del p.G91Vfs*10 | Frame Shift Del (DEL) | VAF 50/334 reads (15%) | called by mutect2, pindel, varscan2
- PRAM1 | c.105del p.K35Nfs*10 | Frame Shift Del (DEL) | VAF 67/434 reads (15%) | called by mutect2, pindel, varscan2
- PRDM14 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 137/650 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRICKLE4 | c.263G>T p.R88M (on ENST00000359201; = p.R128M on NM_013397.6) | Missense Mutation (SNP) | VAF 57/278 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PRKCD | c.248A>C p.E83A | Missense Mutation (SNP) | VAF 38/423 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.354); called by muse, mutect2
- PRODH2 | c.1267G>A p.A423T (on ENST00000301175; = p.A347T on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- PRRC2B | c.4223C>T p.A1408V | Missense Mutation (SNP) | VAF 13/422 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- PRSS36 | c.1971G>T p.Q657H | Missense Mutation (SNP) | VAF 67/459 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PRTG | c.1726T>C p.Y576H | Missense Mutation (SNP) | VAF 73/403 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PSG11 | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 45/335 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSME1 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.583); called by muse, mutect2
- PTBP2 | c.243_244del p.E82Sfs*10 (on ENST00000426398 / NM_001300986.2; = p.E74Sfs*10 on NM_021190.4) | Frame Shift Del (DEL) | VAF 72/373 reads (19%) | called by mutect2, pindel, varscan2
- PTGS1 | c.571del p.Q191Kfs*37 | Frame Shift Del (DEL) | VAF 69/426 reads (16%) | called by pindel, varscan2
- PUS7 | c.596A>G p.D199G | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); called by muse, mutect2
- PXDNL | c.309G>T p.L103= | Splice Region (SNP) | VAF 15/245 reads (6%) | called by muse, mutect2
- QRICH2 | c.4066A>G p.S1356G | Missense Mutation (SNP) | VAF 31/511 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2
- RAD51AP2 | c.946del p.T316Lfs*2 | Frame Shift Del (DEL) | VAF 25/229 reads (11%) | called by mutect2, pindel, varscan2
- RAD51C | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- RAD54L2 | c.92T>A p.V31E | Missense Mutation (SNP) | VAF 51/593 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- RASGRF2 | c.2173T>A p.F725I | Missense Mutation (SNP) | VAF 52/440 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- RBBP4 | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.722); called by muse, mutect2
- RBM34 | c.979G>T p.G327C | Missense Mutation (SNP) | VAF 61/305 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- RECQL4 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 81/541 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- RETSAT | c.1213T>C p.S405P | Missense Mutation (SNP) | VAF 61/365 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RHOBTB3 | c.1424del p.L475* | Frame Shift Del (DEL) | VAF 52/354 reads (15%) | called by mutect2, pindel, varscan2
- RNF212 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 60/310 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); called by muse, varscan2
- ROR2 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RPL13 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RPS26 | c.151A>G p.R51G | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- RSL1D1 | c.564G>T p.K188N | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- RUSC2 | c.1555A>G p.S519G | Missense Mutation (SNP) | VAF 53/493 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2
- SAMSN1 | c.983A>C p.K328T | Missense Mutation (SNP) | VAF 63/360 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- SCAP | c.1145C>A p.A382D | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCN5A | c.1487A>G p.K496R | Missense Mutation (SNP) | VAF 65/314 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SDK2 | c.2564T>C p.V855A | Missense Mutation (SNP) | VAF 31/537 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2
- SDR39U1 | c.455A>G p.Q152R | Missense Mutation (SNP) | VAF 66/316 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SEMA3C | c.1214C>A p.P405H | Missense Mutation (SNP) | VAF 61/321 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
393 further variants in this file (103 protein-altering or splice-affecting, 244 silent, 46 other) are not listed here.
